Surgical pathology report (de-identified scan), TCGA case TCGA-LK-A4O4, project TCGA-MESO (Mesothelioma), tissue source site University of Pittsburgh, specimen TCGA-LK-A4O4-01A (Primary Tumor).

FINAL DIAGNOSIS:

Collection Date:

Summary Statement

The left upper lobe wedge biopsies and left lower lobectomy demonstrate a diffuse malignant mesothelioma, predominantly epithelioid type, involving the visceral parietal pleura and lung parenchyma with involvement of a level 11 lymph node. Pathology stage: T2N1Mx.

PART 1: BONE, "PORTION OF SIXTH RIB", RESECTION -
PORTIONS OF NORMAL BONE AND BONE MARROW WITH HYPERCELLULARITY WITH TRILINEAGE REPRESENTATION AND MATURATION. NO EVIDENCE OF MALIGNANCY.

PART 2: LYMPH NODE, LEVEL 9 LYMPH NODE, BIOPSY -
SOLITARY LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 3: LYMPH NODE, PERIAORTIC LYMPH NODE, BIOPSY -
THREE FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PARTS 4,

7, 8 AND 9: LUNG, "LEFT UPPER LOBE WEDGE", "LEFT LOWER LOBE WEDGE", "LEFT LUNG", AND "LEFT LOWER LOBE", MULTIPLE WEDGE BIOPSIES WITH COMPLETION LEFT LOWER LOBECTOMY -

- A. DIFFUSE MALIGNANT MESOTHELIOMA, PREDOMINANTLY EPITHELIOID TYPE, WITH INVASION OF THE VISCERAL AND PARIETAL PLEURA AND LUNG. ALL EVALUABLE MARGINS FREE (see comment).
- B. RESPIRATORY BRONCHIOLITIS WITH EMPHYSEMATOUS CHANGE.
- C. FOREIGN BODY GIANT CELL REACTION TO EXOGENOUS MATERIAL (HISTORY OF PREVIOUS PLEURECTOMY).
- D. FIVE (5) HILAR LYMPH NODES WITH NO EVIDENCE OF MALIGNANT MESOTHELIOMA. CALCIFIED GRANULOMAS IDENTIFIED.
- E. HYALINE PLEURAL PLAQUES.

PART 5: SOFT TISSUE, "PLEURA", BIOPSY -
PORTIONS OF FIBROADIPOSE TISSUE AND PLEURA ASSOCIATED WITH NERVES AND BLOOD VESSELS. NO EVIDENCE OF MALIGNANCY.

PART 6: LYMPH NODE, LEVEL 11 LYMPH NODE, BIOPSY -
A. SOLITARY LYMPH NODE WITH METASTATIC MALIGNANT MESOTHELIOMA.
B. OLD FIBROCASEOCALCIFIC GRANULOMA. GROCOTT AND ACID FAST STAIN SHOW FOUR MICRON BUDDING YEAST FORMS SUGGESTIVE OF HISTOPLASMA ORGANISMS. CORRELATION WITH CULTURE STUDIES SUGGESTED..

PART 10: DIAPHRAGM, BIOPSY -
CHRONIC PLEURITIS WITH HYALINE PLEURAL PLAQUES. NO EVIDENCE OF MALIGNANCY.

PART 11: LYMPH NODE, "SEGMENT 11 LYMPH NODE", BIOPSY -
THREE (3) FRAGMENTS OF LYMPH NODE WITH NO EVIDENCE OF MALIGNANT MESOTHELIOMA.

COMMENT:

The left lung specimens demonstrate a diffuse malignant mesothelioma, predominantly epithelioid type showing papillary, hyaline and solid tumor growth associated with vascular invasion and focal extensive necrosis. The mesothelioma is unequivocally predominantly of an epithelioid type although very focal zones of spindle growth are identified.

While the pleura show hyaline pleural plaques, the underlying lung parenchyma shows tobacco induce lung injury, predominantly respiratory bronchiolitis and emphysematous change. No evidence of diffuse fibrosis as one would expect in asbestosis is seen, and iron stain failed to demonstrate significant numbers of asbestos type ferruginous bodies.

105-0-3
mesothelioma, epithelioid NOS 9052/3
Site: pleura, NOS

c38.4

9/25/12

Source: NCI Genomic Data Commons file 6d7a6fb3-6788-4c49-9218-5528a96c8897 (TCGA-LK-A4O4.2F75B668-8CE5-4228-AE5C-4C4F087C6930.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).